Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PP, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PP-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, tubular 8211/3
Site: Body of stomach C16.2
JW 3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

- I) Greater omentum - uninvolved by neoplasia.
II) Product of subtotal gastrectomy.
- Tubular moderately differentiated adenocarcinoma measuring 9.5 x 7.0 cm in major axes (intestinal type of Lauren).
- Tumor infiltrates the adipose tissue and the peritoneum.
- Presence of extensive areas of tumoral necrosis.
- Lymphatic tumoral infiltration.
- Venous and perineural infiltration not detected.
- Intense stromal desmoplasia.
- Absence of intratumoral inflammatory infiltrate.
- Non tumoral gastric mucosae exhibiting chronic gastritis, moderate atrophy intestinal metaplasia areas.
- Surgical margins uninvolved by neoplasia.

- III) Standardized lymphadenectomy
Right paracardics
- Lymph node uninvolved by neoplasia (0/1).

- Lesser curvature.
- Uninvolved by neoplasia (0/7).

- Suprapylorics.
- uninvolved by neoplasia (0/1).

- Infrapylorics.
- Uninvolved by neoplasia (0/1).

- Celiac trunk.
- uninvolved by neoplasia (0/1).

- Right gastroepiploic.
- Metastatic adenocarcinoma in 3 of the 5 lymph nodes dissected (3/5).

- Left gastroepiploic.
- Uninvolved by neoplasia (0/2).

- Anterior hepatic artery.
- uninvolved by neoplasia (0/1).

Source: NCI Genomic Data Commons file 26d13f0a-2987-476a-a0ba-1ea0dc1cbc00 (TCGA-VQ-A8PP.18F47566-E1DC-4229-AF5A-60A1B79C48CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).